Gene-level copy-number profile of tumor specimen ALCH-B1XK-TTP1-A from ALCHEMIST case ALCH-B1XK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.6 years (26,134 days).
Specimen ALCH-B1XK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fd06ae1d-e8af-40da-bdec-f8b23fa7bfbc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1XK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/9c3b9b81-9251-46de-be8e-1a11269cc9b2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 989; copy number 2: 56,653; copy number 3: 629; copy number 4: 66; copy number 6: 7; copy number 9: 2; copy number 18: 5; copy number 42: 3.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,292,390–1,309,609, 2 genes (within-gene range 0–2): ACAP3, MIR6726.
- chr2:72,129,238–72,148,038, 1 gene: CYP26B1.
- chr2:130,139,287–130,145,134, 1 gene (within-gene range 0–2): CCDC74B.
- chr2:238,100,340–238,168,900, 4 genes: ESPNL, KLHL30, KLHL30-AS1, ERFE.
- chr4:1,986,384–1,986,477, 1 gene (within-gene range 0–2): MIR943.
- chr5:470,456–524,449, 2 genes (within-gene range 0–3): SLC9A3, SLC9A3-AS1.
- chr7:5,526,409–5,563,902, 3 genes (within-gene range 0–2): ACTB, AC006483.2, AC006483.1.
- chr9:61,581,813–61,666,386, 5 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr9:136,249,978–136,251,205, 1 gene: CR392000.1.
- chr12:131,894,622–131,929,351, 3 genes (within-gene range 0–2): ULK1, AC131009.4, AC131009.1.
- chr14:19,324,708–19,327,716, 1 gene: AL929602.1.
- chr14:104,579,764–104,590,515, 2 genes (within-gene range 0–2): C14orf180, BX927359.1.
- chr14:105,486,317–105,499,575, 3 genes: CRIP1, AL928654.3, TEDC1.
- chr16:87,834,592–87,837,663, 2 genes (within-gene range 0–3): MIR6775, AC126696.2.
- chr17:2,712,309–2,712,833, 1 gene: AC005696.1.
- chr19:13,874,699–13,875,011, 2 genes (within-gene range 0–2): MIR181C, MIR181D.
- chr21:43,322,417–43,366,566, 3 genes: LINC00322, LINC01679, AP001046.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,768,977–7,795,870, 2 genes, copy number 9: FAM90A10P, PRR23D3P.
- chr9:60,914,407–61,453,030, 12 genes, copy number 6–18: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr22:18,906,028–18,947,732, 3 genes, copy number 42 (within-gene range 3–42): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 872. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
